Somatic mutation profile of tumor specimen TCGA-X6-A7WC-01A (aliquot TCGA-X6-A7WC-01A-12D-A351-09) from TCGA case TCGA-X6-A7WC, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 74.6 years (27,252 days).
Specimen TCGA-X6-A7WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a79e131-7648-495a-9af2-5e35345d80f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A7WC-10A (Blood Derived Normal), aliquot TCGA-X6-A7WC-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb09fd61-8118-4062-b4d4-88356b65fe7f

The open-access MAF lists 91 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 23, Frame Shift Del 6, Intron 3, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 62/79 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.5575G>T p.V1859F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs770773955, COSV99265779; called by muse, mutect2, varscan2
- ARL4C | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.816); catalogued as COSV100326947; called by muse, mutect2
- ATP12A | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.217); catalogued as COSV99517710; called by muse, mutect2, varscan2
- ATP8A1 | c.3023A>G p.H1008R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV100046280; called by muse, mutect2, varscan2
- C3 | c.4017A>T p.Q1339H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99836695; called by muse, mutect2, varscan2
- CACNA1F | c.4145G>T p.G1382V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544901; called by muse, mutect2, varscan2
- CCDC27 | c.1137C>A p.D379E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53904352, COSV99622537; called by muse, mutect2, varscan2
- CDK13 | c.3076A>T p.R1026* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99475589; called by muse, mutect2
- CIB4 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs771633268, COSV56603839, COSV99995120; called by muse, mutect2, varscan2
- COL1A1 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99866871, COSV99867287; called by muse, mutect2, varscan2
- DEFB113 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.017); catalogued as COSV100435396; called by muse, mutect2, varscan2
- DHRS2 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51630751, COSV99159127; called by muse, mutect2, varscan2
- DISP3 | c.1849A>T p.S617C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99608735; called by muse, mutect2, varscan2
- DMXL1 | c.2255-1G>T p.X752_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100224022; called by muse, mutect2, varscan2
- DNAH11 | c.8276T>C p.F2759S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100179348; called by muse, varscan2
- DNAH11 | c.8540C>A p.P2847H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100179349; called by muse, mutect2, varscan2
- DOCK6 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1223608233, COSV99370993; called by muse, mutect2, varscan2
- EPHA8 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.986); catalogued as COSV99384898; called by muse, mutect2
- FOXH1 | c.185A>C p.Q62P | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV100023815; called by muse, mutect2, varscan2
- GABRA2 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100734301, COSV62916740; called by muse, mutect2, varscan2
- GPALPP1 | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62705961; called by muse, mutect2
- IARS2 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100228339; called by muse, mutect2, varscan2
- ICE1 | c.4084G>T p.D1362Y | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV56827853; called by muse, mutect2, varscan2
- IQGAP1 | c.4359A>T p.Q1453H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV99185028; called by muse, mutect2, varscan2
- IVL | c.1046A>G p.Q349R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.404); catalogued as COSV100908168; called by muse, mutect2, varscan2
- LPIN2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55245336, COSV99858409; called by muse, mutect2, varscan2
- MANEA | c.520A>T p.R174* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100721541; called by muse, mutect2, varscan2
- MYO7A | c.3886C>T p.R1296W | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs773004793, COSV101289146; called by mutect2, varscan2
- NOS1 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV100500670; called by muse, mutect2, varscan2
- NUDT7 | c.522del p.F175Lfs*17 | Frame Shift Del (DEL) | VAF 41/96 reads (43%) | catalogued as COSV51745267; called by mutect2, pindel, varscan2
- OR2M3 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV101513434; called by muse, mutect2, varscan2
- OR5AP2 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV57258407; called by muse, mutect2, varscan2
- OR5T2 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57589962, COSV57590992; called by muse, mutect2, varscan2
- OTOGL | c.6788G>A p.R2263Q (on ENST00000547103; = p.R2254Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs759534300, COSV100087317, COSV100087577; called by muse, mutect2, varscan2
- PCDH9 | c.3353G>T p.G1118V (on ENST00000377865 / NM_203487.3; = p.G1084V on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.853); catalogued as COSV60549631; called by muse, mutect2, varscan2
- PCDHA11 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100250695; called by muse, mutect2, varscan2
- PCSK9 | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV100135228, COSV56164581; called by muse, mutect2
- PDLIM2 | c.628G>A p.E210K (on ENST00000397760; = p.E460K on NM_021630.6) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99747627; called by muse, mutect2, varscan2
- PLEKHG2 | c.3724G>T p.G1242C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV99217510; called by muse, mutect2, varscan2
- PLPP2 | c.141C>A p.Y47* | Nonsense Mutation (SNP) | VAF 37/165 reads (22%) | catalogued as COSV99514682; called by muse, mutect2, varscan2
- PTH2R | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55914986, COSV99782497; called by muse, mutect2
- RHPN2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99577641; called by muse, mutect2, varscan2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- RPH3A | c.778T>C p.S260P (on ENST00000389385 / NM_001143854.2; = p.S256P on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV101231826; called by muse, mutect2, varscan2
- RYR1 | c.12523C>T p.P4175S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV100615810; called by muse, mutect2, varscan2
- SCN7A | c.1164G>T p.L388F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264276953, COSV101313244; called by muse, mutect2, varscan2
- SLC25A25 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV100895314; called by muse, mutect2, varscan2
- SLC44A5 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100902078, COSV63771448; called by muse, mutect2
- TANGO6 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs946688538, COSV99936246; called by muse, mutect2, varscan2
- TBKBP1 | c.1754G>A p.S585N | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100659146; called by muse, mutect2, varscan2
- TCHHL1 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs573540377, COSV100916542, COSV64286157; called by muse, mutect2, varscan2
- TDRKH | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100917960; called by muse, mutect2
- TFAP2D | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99145939; called by muse, mutect2, varscan2
- TGM5 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV55013126; called by muse, mutect2, varscan2
- TLDC2 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99455957; called by muse, mutect2, varscan2
- TRPM8 | c.2920C>A p.L974M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224084; called by muse, mutect2, varscan2
- ZBTB7C | c.856A>G p.N286D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1173481573, COSV100134451; called by muse, mutect2, varscan2
- ZNF282 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100021692; called by muse, mutect2, varscan2
- ATRX | c.4851_4861del p.D1618Gfs*8 | Frame Shift Del (DEL) | VAF 47/70 reads (67%) | called by mutect2, pindel, varscan2
- DUSP5 | c.1070del p.P357Lfs*43 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- INVS | c.2672_2711del p.I891Rfs*39 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel
- MOV10 | c.8del p.S3Ifs*59 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.908del p.P303Qfs*42 | Frame Shift Del (DEL) | VAF 38/82 reads (46%) | called by mutect2, pindel*, varscan2
- ABCB1 | c.1893A>C p.A631= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99713120; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2178A>G p.R726= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99719016; called by muse, mutect2, varscan2
- BLNK | c.1224C>T p.A408= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99813927; called by muse, mutect2, varscan2
- CDCA3 | c.165G>T p.L55= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99976945; called by muse, mutect2, varscan2
- EYA1 | c.765T>C p.T255= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV100379476; called by muse, mutect2
- GCKR | c.441C>A p.A147= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99253913; called by muse, mutect2
- IGSF5 | c.399T>C p.S133= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV101012070; called by muse, mutect2, varscan2
- INSR | c.159C>T p.C53= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100252309; called by muse, mutect2, varscan2
- LIMCH1 | c.429C>T p.Y143= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs376258134; called by muse, mutect2, varscan2
- MUC17 | c.6393T>C p.S2131= | Silent (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- MYCBP2 | c.2811A>G p.G937= (on ENST00000357337; = p.G975= on NM_015057.5) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100630450; called by muse, mutect2, varscan2
- OR2J2 | c.309C>T p.Y103= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV101013378; called by muse, mutect2, varscan2
- PCDHA10 | c.1350C>T p.N450= | Silent (SNP) | VAF 83/192 reads (43%) | catalogued as rs782631166, COSV56474466, COSV56496941; called by muse, mutect2, varscan2
- PPP1R12B | c.312G>A p.L104= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100407360; called by muse, mutect2, varscan2
- RBMXL2 | c.351C>A p.G117= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1439985493, COSV100182257; called by muse, varscan2
- RNF14 | c.1422C>T p.D474= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV100641232; called by muse, mutect2
- RYR3 | c.7464C>G p.L2488= (on ENST00000389232; = p.L2489= on NM_001036.6) | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV101212854; called by muse, mutect2, varscan2
- SIGLEC9 | c.579C>A p.T193= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV99142616; called by muse, mutect2, varscan2
- SLAMF7 | c.174C>A p.T58= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100833285; called by muse, mutect2, varscan2
- SLC47A2 | c.780C>T p.T260= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs771632389, COSV57629150; called by muse, mutect2
- TEKT5 | c.438G>A p.S146= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs748005920, COSV99296112, COSV99296121; called by muse, mutect2, varscan2
- TRIML2 | c.240T>A p.A80= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV100456075; called by muse, mutect2, varscan2
- TXNRD2 | c.183G>T p.L61= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs776734424, COSV100538815; called by muse, mutect2, varscan2
- CALCR | c.52-3302C>T | Intron (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100810557, COSV100810604; called by muse, mutect2, varscan2
- GRID1 | c.236-58112G>A | Intron (SNP) | VAF 12/33 reads (36%) | catalogued as rs1026858249, COSV100024261; called by muse, mutect2
- LY9 | c.454+1742C>T | Intron (SNP) | VAF 17/77 reads (22%) | catalogued as COSV54432271; called by muse, mutect2, varscan2
